FM case AD4083 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/3159af11-22cc-45c3-97a4-9fb71a7d0812

Male, 75.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); specimen biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
